Somatic mutation profile of tumor specimen TCGA-VQ-AA6D-01A (aliquot TCGA-VQ-AA6D-01A-11D-A410-08) from TCGA case TCGA-VQ-AA6D, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,090 days).
Specimen TCGA-VQ-AA6D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdcb48f8-d61e-4267-bf8b-fdc08fb18511.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6D-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6D-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32c24e17-d77e-414d-9ec8-8c3102c7406b

The open-access MAF lists 827 somatic variants for this specimen: 631 protein-altering or splice-affecting, 178 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 496, Silent 178, Frame Shift Del 69, Nonsense Mutation 26, Frame Shift Ins 13, In Frame Del 10, Intron 7, Splice Region 7, Splice Site 7, RNA 5, 3'UTR 4, Nonstop Mutation 3.

Variants (750 of 827; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.11700del p.K3900Nfs*8 | Frame Shift Del (DEL) | VAF 6/71 reads (8%) | catalogued as rs1553421626; ClinVar: likely pathogenic; called by mutect2, pindel
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MPC1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs387907237, CM126146, COSV59132729; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RECQL4 | c.3061C>T p.R1021W | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs137853232, CM060450; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC18A2 | c.711del p.F238Sfs*48 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as rs762879329, COSV53693545; ClinVar: likely pathogenic; called by mutect2, pindel
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VWF | c.2435del p.P812Rfs*31 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | catalogued as rs62643632, CD920917, CM074633, COSV54614968; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AACS | c.710T>G p.V237G | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99908146; called by muse, mutect2, varscan2
- AARD | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100991921; called by muse, mutect2, varscan2
- AARS2 | c.1595A>C p.E532A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.216); catalogued as COSV99771548; called by mutect2, varscan2
- ABCA13 | c.3067G>T p.G1023* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV70028418, COSV70032542; called by muse, mutect2, varscan2
- ABCA9 | c.2657A>C p.E886A | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs1226918966, COSV100383269; called by muse, mutect2
- ABCC10 | c.1978C>T p.R660W (on ENST00000372530 / NM_001198934.2; = p.R632W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs746160379, COSV55089176; called by muse, mutect2, varscan2
- ABCF2 | c.893T>C p.M298T | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV99734619; called by muse, mutect2, varscan2
- ABR | c.334G>A p.A112T (on ENST00000302538 / NM_021962.5; = p.A75T on NM_001092.5) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.557); catalogued as rs146820192; called by muse, mutect2, varscan2
- ACACB | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs375473600; called by muse, mutect2, varscan2
- ACIN1 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99399870; called by muse, mutect2
- ACO2 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs1345131134, COSV99347559; called by muse, mutect2
- ACOX2 | c.1937A>G p.Y646C | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100250219; called by muse, mutect2, varscan2
- ACP5 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99520192; called by muse, mutect2, varscan2
- ACTR3 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.093); catalogued as COSV99603778; called by muse, mutect2
- ACVR2B | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs539715843, COSV99070885; called by muse, mutect2, varscan2
- ADAMTS12 | c.915+2T>C p.X305_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100711302; called by muse, mutect2, varscan2
- ADAMTS16 | c.2171A>G p.N724S | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs780568724, COSV99941928, COSV99943367; called by muse, mutect2, varscan2
- ADAMTS20 | c.4606A>C p.M1536L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101239700, COSV67132994; called by muse, mutect2, varscan2
- ADCY6 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57168480; called by muse, mutect2
- ADH1C | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs769121542, COSV72463373; called by muse, mutect2, varscan2
- AGBL5 | c.908+2T>C p.X303_splice | Splice Site (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100549215; called by muse, mutect2
- AHCTF1 | c.6685A>G p.R2229G (on ENST00000366508; = p.R2203G on NM_015446.5) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58251473; called by muse, mutect2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100662630, COSV100662936; called by muse, mutect2
- ALDH1A2 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99990908; called by muse, mutect2, varscan2
- ALDH1L1 | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV99857163; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as COSV51845823; called by mutect2, varscan2
- ANO4 | c.1619C>T p.A540V (on ENST00000392977 / NM_001286615.2; = p.A505V on NM_178826.4) | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.617); catalogued as rs1014816581, COSV100152887; called by muse, mutect2, varscan2
- AP1G2 | c.1606A>G p.T536A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV99846269; called by muse, mutect2, varscan2
- AP3B2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99916692; called by muse, mutect2, varscan2
- APOB | c.2326T>C p.Y776H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536328155, COSV99266524; called by muse, mutect2, varscan2
- ARF3 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV99873187; called by muse, mutect2
- ARG1 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.483); catalogued as COSV51580827; called by muse, mutect2, varscan2
- ARHGAP39 | c.2200A>G p.T734A | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99431735; called by muse, mutect2, varscan2
- ARHGEF17 | c.5254G>A p.V1752M | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374378252; called by muse, mutect2, varscan2
- ARHGEF38 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV99486406; called by muse, mutect2, varscan2
- ARIH2 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1370190130, COSV100711362; called by muse, mutect2
- ARL13B | c.583G>A p.D195N (on ENST00000394222 / NM_001174150.2; = p.D88N on NM_144996.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs1393787507, COSV100115605; called by muse, mutect2, varscan2
- ARMC5 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99192624, COSV99192846; called by muse, mutect2, varscan2
- ASCC2 | c.1790T>C p.V597A | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV100316358; called by muse, mutect2
- ASIC4 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.31); catalogued as COSV100761799; called by muse, mutect2, varscan2
- ATP10A | c.2473T>C p.C825R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV100791382; called by muse, mutect2, varscan2
- ATP13A2 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs555691965, COSV100454250, COSV58702625; called by muse, mutect2, varscan2
- ATP1A1 | c.279T>G p.C93W | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99814608; called by muse, mutect2
- ATP2B2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs984601396, COSV100660154, COSV100660698; called by muse, mutect2, varscan2
- ATP2B2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs945844574, COSV59489385; called by muse, mutect2
- ATP8A1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as rs755553887, COSV100046625; called by muse, varscan2
- ATP8B3 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371318224; called by muse, mutect2, varscan2
- B3GNT8 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV99524668; called by muse, mutect2, varscan2
- BAZ2B | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.081); catalogued as COSV100600797; called by muse, mutect2, varscan2
- BCAR1 | c.1997A>G p.Y666C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99366897; called by muse, mutect2, varscan2
- BFAR | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as rs1385230099, COSV99902335; called by muse, mutect2, varscan2
- BIRC6 | c.13798C>T p.R4600C | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs773885941, COSV101428443; called by muse, mutect2, varscan2
- BMP5 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755749791, COSV100895661; called by muse, mutect2, varscan2
- BMT2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99774722; called by muse, mutect2, varscan2
- BNC2 | c.986A>T p.N329I | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101033731; called by muse, mutect2, varscan2
- BSN | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772486017, COSV99609014; called by muse, mutect2, varscan2
- BTAF1 | c.4016G>T p.G1339V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99795521; called by muse, mutect2, varscan2
- BTBD9 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100022146; called by muse, mutect2, varscan2
- C12orf42 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.966); catalogued as COSV100172434; called by muse, mutect2
- C2orf76 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs771993808, COSV100601741; called by mutect2, varscan2
- C5AR2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); catalogued as rs771387679, COSV99953814; called by muse, mutect2, varscan2
- C6orf58 | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.16); catalogued as COSV100314958; called by muse, mutect2, varscan2
- CACNA1E | c.817T>G p.C273G | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100703820; called by muse, mutect2, varscan2
- CACNA1E | c.6650A>G p.Q2217R (on ENST00000367573 / NM_001205293.3; = p.Q2174R on NM_000721.4) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100703826; called by muse, mutect2, varscan2
- CACNA1G | c.5344C>T p.H1782Y | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100662110; called by muse, mutect2, varscan2
- CAMTA2 | c.1766-2A>C p.X589_splice | Splice Site (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100772672; called by muse, mutect2
- CASP9 | c.1051T>G p.F351V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100423855; called by muse, mutect2
- CATSPER3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs779835422, COSV99254216; called by muse, mutect2, varscan2
- CATSPERE | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100835249; called by muse, mutect2, varscan2
- CBLN1 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99535741; called by muse, mutect2, varscan2
- CCDC148 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99320863, COSV99321638; called by muse, mutect2
- CCDC18 | c.3391G>T p.D1131Y (on ENST00000343253 / NM_001306076.1; = p.D1132Y on NM_206886.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100159762; called by muse, mutect2
- CCDC33 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV100351583; called by muse, mutect2, varscan2
- CCR5 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs766082963, COSV52752200; called by muse, mutect2, varscan2
- CCR9 | c.916G>A p.A306T (on ENST00000357632 / NM_031200.3; = p.A294T on NM_006641.4) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1346189977; called by muse, mutect2
- CDC16 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1401731336, COSV99373021; called by muse, mutect2, varscan2
- CDC42EP1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as rs772587344, COSV99312571; called by muse, mutect2, varscan2
- CDKN1B | c.286A>C p.K96Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as CM121087, COSV99963999; called by muse, mutect2, varscan2
- CELF4 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100611785; called by muse, mutect2, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CERS3 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99432309; called by muse, mutect2, varscan2
- CGN | c.2170A>G p.T724A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV99642519; called by muse, mutect2
- CGNL1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs138103109, COSV55562951; called by muse, mutect2, varscan2
- CHST4 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100632887; called by muse, mutect2, varscan2
- CIZ1 | c.2459A>G p.K820R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.765); catalogued as COSV99476963; called by muse, mutect2, varscan2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs754415052; called by mutect2, varscan2
- CLIC5 | c.1163A>G p.N388S (on ENST00000185206 / NM_001370649.1; = p.N229S on NM_016929.5) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99484882; called by muse, mutect2, varscan2
- CLN8 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.103); catalogued as COSV100486090; called by muse, mutect2, varscan2
- CLSTN3 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs988948667, COSV56934226; called by muse, mutect2
- CNTN1 | c.2612T>G p.L871R | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100751603; called by muse, mutect2, varscan2
- CNTNAP2 | c.3925G>A p.A1309T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as rs530757880, COSV100668192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG1 | c.2837A>T p.D946V | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV100245379, COSV55429907; called by muse, mutect2
- COL19A1 | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV100506774; called by muse, varscan2
- COL1A1 | c.3263del p.G1088Dfs*20 | Frame Shift Del (DEL) | VAF 48/187 reads (26%) | catalogued as CM144919, CM930147; called by mutect2, pindel, varscan2
- COL6A6 | c.5101G>A p.G1701R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100650518; called by muse, mutect2, varscan2
- COL7A1 | c.7667A>G p.N2556S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs754928076, COSV100096832; called by muse, mutect2, varscan2
- COL9A1 | c.2052A>T p.E684D | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV57882866; called by muse, mutect2, varscan2
- COP1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as rs749431618, COSV58169259; called by muse, mutect2, varscan2
- CPA4 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs570075096, COSV55983252, COSV55983743; called by muse, mutect2, varscan2
- CPB2 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99473194; called by muse, mutect2, varscan2
- CREB5 | c.214G>A p.V72M (on ENST00000357727 / NM_182898.4; = p.V65M on NM_004904.3) | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754514486, COSV100745006; called by muse, mutect2
- CRYGA | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1474537753, COSV58015164; called by muse, mutect2, varscan2
- CSNK1E | c.1249T>C p.*417Rext*29 | Nonstop Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100725049; called by muse, mutect2, varscan2
- CSPG4 | c.3437A>G p.D1146G | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100413893, COSV99079533; called by muse, mutect2, varscan2
- CTAGE6 | c.1349T>G p.F450C | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV101417861; called by muse, varscan2
- CUL3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs368330682, COSV100024441; called by mutect2, varscan2
- CYP2A6 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV56533848; called by muse, mutect2, varscan2
- CYP2A7 | c.185G>T p.S62I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99394260; called by muse, mutect2, varscan2
- CYSLTR1 | c.671del p.N224Ifs*9 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs766746913; called by mutect2, varscan2
- DACH2 | c.130A>C p.N44H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV100913523; called by muse, mutect2, varscan2
- DDX27 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs894366245, COSV65630653; called by muse, mutect2
- DDX39B | c.489_491del p.K163del | In Frame Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs758489522; called by pindel, varscan2
- DDX58 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV101152969; called by muse, varscan2
- DENND1A | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101012132; called by muse, mutect2, varscan2
- DENND4C | c.5743G>A p.A1915T (on ENST00000434457 / NM_001330640.2; = p.A1866T on NM_017925.7) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV100194567; called by muse, mutect2
- DEPDC1 | c.1476A>C p.Q492H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100920403; called by muse, mutect2, varscan2
- DERL1 | c.756A>G p.*252Wext*47 | Nonstop Mutation (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99418589; called by muse, mutect2
- DGAT2L6 | c.81T>G p.F27L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100284054; called by muse, mutect2, varscan2
- DIP2C | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs781236230, COSV55146465, COSV55173386; called by muse, mutect2, varscan2
- DLG5 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 11/111 reads (10%) | catalogued as COSV100967581; called by muse, mutect2, varscan2
- DLGAP2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.711); catalogued as rs946633525, COSV70095560; called by muse, mutect2, varscan2
- DMAC2L | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs755906483, COSV99816503; called by muse, mutect2, varscan2
- DMD | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM051909, COSV99923882; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs745893364; called by mutect2, varscan2
- DNA2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs760075530, COSV100622343; called by muse, mutect2, varscan2
- DNAH11 | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as rs756873483, COSV100179737; called by muse, mutect2, varscan2
- DNAH3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs371453732; called by mutect2, varscan2
- DNAH5 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs767655417, COSV54226869; called by muse, mutect2, varscan2
- DNLZ | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as COSV99396023; called by muse, mutect2
- DNMT3B | c.1577T>G p.M526R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99142436; called by muse, mutect2, varscan2
- DOCK7 | c.3609A>T p.E1203D (on ENST00000635253 / NM_001367561.1; = p.E1172D on NM_033407.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV99225036; called by muse, mutect2, varscan2
- DRP2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs201156733, COSV65811862; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.412); catalogued as COSV99709224; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99143706; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs751377941; called by mutect2, varscan2
- DYTN | c.1601T>G p.L534R | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs760078404, COSV101510870, COSV71752270; called by muse, mutect2, varscan2
- DZIP1 | c.2086G>A p.A696T (on ENST00000347108; = p.A677T on NM_014934.5) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV61265254; called by muse, mutect2
- ECHDC2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781602712, COSV64301283; called by muse, mutect2, varscan2
- ECT2L | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs548413493, COSV100872064, COSV62882730; called by muse, mutect2, varscan2
- EDN2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764912588, COSV101006296; called by muse, mutect2, varscan2
- EFCAB6 | c.4258T>C p.S1420P | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99413797; called by muse, mutect2, varscan2
- EFCAB7 | c.161T>A p.I54N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99371203; called by muse, mutect2, varscan2
- EIF2AK3 | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs779996738, COSV57547661; called by muse, mutect2, varscan2
- EIF3J | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as COSV99969062; called by muse, mutect2, varscan2
- EMC1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs200540304, COSV100916459; called by muse, mutect2, varscan2
- EMILIN1 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV99566360; called by muse, mutect2, varscan2
- EML3 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99604386; called by muse, mutect2
- EPHA6 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101064041; called by muse, mutect2, varscan2
- EPHB3 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376071253, COSV57804035; called by muse, mutect2, varscan2
- EPPK1 | c.4673C>T p.A1558V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs782354255, COSV73262658; called by muse, mutect2
- EPS15 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100869568; called by muse, mutect2, varscan2
- EPS8 | c.1097A>T p.N366I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99843373; called by muse, mutect2, varscan2
- ERCC2 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs751318902, COSV67270315; called by muse, mutect2, varscan2
- ERP29 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs752987002, COSV55673422; called by mutect2, varscan2
- ESF1 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.958); catalogued as COSV99176422; called by muse, mutect2, varscan2
- ESPL1 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs149272357; called by muse, mutect2
- ESRRG | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100753376, COSV63169122; called by muse, mutect2
- ESYT3 | c.2425A>G p.T809A | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101272708; called by muse, mutect2, varscan2
- EXOC2 | c.1380G>C p.L460F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV100033863, COSV100034293; called by mutect2, varscan2
- F5 | c.2133T>A p.D711E | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100889167; called by muse, mutect2
- FAM120C | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV60261971; called by muse, mutect2, varscan2
- FAM131C | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs549929286, COSV65153220; called by mutect2, varscan2
- FAM20A | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.996); catalogued as COSV99873387; called by muse, mutect2
- FAM83D | c.521A>T p.D174V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99465328; called by muse, mutect2, varscan2
- FAM98A | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV53210555; called by muse, mutect2, varscan2
- FBP2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs550526190, COSV64695235; called by muse, mutect2, varscan2
- FER1L6 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV101206017; called by muse, mutect2
- FGD3 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs778590186, COSV61595838; called by muse, mutect2, varscan2
- FLG2 | c.5161A>G p.T1721A | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs756698387, COSV66175199; called by muse, mutect2, varscan2
- FLNA | c.3973G>T p.E1325* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as COSV100774881; called by muse, mutect2, varscan2
- FLNA | c.2150G>A p.C717Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV100774882, COSV100775026; called by muse, mutect2
- FLOT2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as COSV101204783; called by muse, mutect2, varscan2
- FLT1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374335323, COSV56723065, COSV99167652; called by muse, mutect2
- FMN2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs748393494, COSV60431235; called by muse, mutect2
- FOLR3 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs371010355; called by muse, mutect2, varscan2
- FOXD4L1 | c.497T>A p.V166D | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs751203582, COSV99380650; called by muse, mutect2, varscan2
- FOXN3 | c.1367C>T p.A456V (on ENST00000261302; = p.A434V on NM_005197.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV54313357, COSV54319174; called by muse, mutect2
- FRAS1 | c.4663G>T p.A1555S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV99353843; called by muse, mutect2
- FRMD1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs372120473; called by muse, mutect2, varscan2
- FTSJ1 | c.285G>A p.L95= | Splice Region (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99191426; called by muse, mutect2, varscan2
- FURIN | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361467453, COSV51580311; called by muse, mutect2, varscan2
- FUT4 | c.1061_1062del p.Q354Rfs*195 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs773047836; called by mutect2, varscan2
- GABRD | c.661T>G p.F221V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV101059557; called by muse, mutect2, varscan2
- GALNT2 | c.816C>T p.G272= | Splice Region (SNP) | VAF 19/76 reads (25%) | catalogued as rs142736956, COSV64195396; called by muse, mutect2
- GBP1 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100976283; called by muse, mutect2
- GBP6 | c.801T>G p.I267M | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV100969590, COSV65010668; called by muse, mutect2
- GBX2 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60445533; called by muse, mutect2, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as rs755348339; called by mutect2, pindel, varscan2
- GDF6 | c.275T>G p.V92G | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99748260; called by muse, mutect2, varscan2
- GGA3 | c.1475T>C p.L492S (on ENST00000537686 / NM_138619.4; = p.L459S on NM_014001.5) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99822155; called by muse, mutect2, varscan2
- GLA | c.1205G>T p.R402M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV99516478; called by muse, mutect2
- GLO1 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100974102; called by muse, mutect2, varscan2
- GNAS | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.566); catalogued as COSV58332059; called by muse, mutect2, varscan2
- GNRHR | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV99892256; called by muse, mutect2, varscan2
- GPBP1 | c.1047A>C p.E349D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99302915; called by muse, mutect2, varscan2
- GRIA1 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99600886; called by muse, mutect2, varscan2
- GRIA4 | c.801T>A p.F267L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.216); catalogued as COSV99232772; called by muse, mutect2, varscan2
- GRID1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100024973; called by muse, mutect2
- GRIN2A | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100408980, COSV100410375; called by muse, mutect2, varscan2
- GSE1 | c.1522_1524del p.K508del | In Frame Del (DEL) | VAF 9/17 reads (53%) | catalogued as rs1302316473; called by mutect2, varscan2
- GSPT2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468233; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1590T>A p.D530E | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV99734986; called by muse, mutect2, varscan2
- GTPBP1 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53285791; called by muse, mutect2, varscan2
- H4C4 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100534449; called by muse, mutect2, varscan2
- HAGH | c.638del p.P213Rfs*61 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs751524326; called by mutect2, pindel
- HAVCR2 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100324839; called by muse, mutect2
- HEATR5A | c.5027G>T p.G1676V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV101120221; called by muse, mutect2, varscan2
- HECW1 | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV101223965, COSV67825361; called by muse, mutect2, varscan2
- HERC1 | c.13772G>A p.R4591H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416525368, COSV101496699; called by mutect2, varscan2
- HERC5 | c.2725A>G p.I909V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV99987895; called by muse, mutect2, varscan2
- HIF1A | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.385); catalogued as COSV60188766; called by muse, mutect2, varscan2
- HRNR | c.2815G>T p.G939W | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs200852837, COSV64254327, COSV64258947; called by muse, varscan2
- HSPA12A | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV65020802, COSV65022370; called by muse, mutect2, varscan2
- HTR1A | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60499893; called by muse, mutect2
- HTR1F | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100138161; called by muse, mutect2, varscan2
- IDE | c.1130T>C p.V377A | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV99794142; called by muse, mutect2
- IFNA5 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as rs371906885; called by muse, mutect2, varscan2
- IFNA6 | c.504A>C p.R168S | Missense Mutation (SNP) | VAF 35/370 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV101207025; called by muse, mutect2
- IGFN1 | c.3278G>A p.R1093H (on ENST00000295591 / NM_001367841.1; = p.R3550H on NM_001164586.2) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs369774577, COSV55181338; called by muse, mutect2, varscan2
- IGHMBP2 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139497493; called by muse, mutect2, varscan2
- IGSF1 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV100812182; called by muse, mutect2
- IGSF11 | c.816T>G p.N272K (on ENST00000393775 / NM_001015887.3; = p.N271K on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.073); catalogued as COSV100677525, COSV61165326; called by muse, mutect2
- IGSF9B | c.1301C>A p.A434D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100317987; called by muse, mutect2, varscan2
- IMP4 | c.687C>T p.F229= | Splice Region (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99383782; called by muse, mutect2, varscan2
- ING1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV58166814; called by muse, mutect2, varscan2
- IQGAP2 | c.4418C>T p.A1473V | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs745748799, COSV57173871; called by muse, mutect2, varscan2
- IRF4 | c.780A>C p.E260D | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV101110906; called by muse, mutect2, varscan2
- ITGA6 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.735); catalogued as COSV99905703; called by muse, mutect2, varscan2
- ITPKB | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs764606849, COSV55261498; called by muse, mutect2, varscan2
- JAML | c.359T>C p.L120P (on ENST00000356289 / NM_001098526.2; = p.L110P on NM_153206.3) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99409619; called by muse, mutect2, varscan2
- KAT8 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs963784714, COSV54898951; called by mutect2, varscan2
- KBTBD13 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1212195070, COSV101416699; called by muse, mutect2, varscan2
- KBTBD4 | c.1149del p.E386Rfs*27 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | catalogued as rs749522423; called by mutect2, pindel, varscan2
- KCNG4 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.011); catalogued as COSV57586069; called by muse, mutect2, varscan2
- KCNH5 | c.159T>G p.Y53* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV100527165; called by muse, mutect2, varscan2
- KCNH6 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs771454089, COSV59004928; called by muse, mutect2, varscan2
- KCNK15 | c.606C>G p.F202L | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV100865160; called by muse, mutect2, varscan2
- KCNMB1 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV51131382, COSV99211278; called by muse, mutect2, varscan2
- KCNMB2 | c.80A>C p.D27A | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as COSV100843983, COSV64200354; called by muse, mutect2
- KCNMB3 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV100566754, COSV62895161; called by muse, mutect2, varscan2
- KCNT1 | c.2821T>A p.F941I (on ENST00000488444; = p.F960I on NM_020822.3) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99706108; called by muse, mutect2, varscan2
- KEL | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100787168; called by muse, mutect2
- KHDC4 | c.384+2T>C p.X128_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100850829; called by muse, mutect2, varscan2
- KIAA0895 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99732528; called by muse, mutect2, varscan2
- KIAA1841 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99693923; called by muse, mutect2, varscan2
- KIF3C | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99267614; called by muse, mutect2, varscan2
- KIF5C | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV101276163; called by muse, mutect2
- KNDC1 | c.3997G>T p.V1333L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV100465480, COSV58845357; called by muse, mutect2, varscan2
- KRT32 | c.872T>C p.M291T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1483082550, COSV56787184; called by muse, mutect2, varscan2
- KRTAP27-1 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV101239737; called by muse, mutect2, varscan2
- LAMB2 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100565342; called by muse, mutect2, varscan2
- LAMB4 | c.4684G>A p.A1562T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99224752; called by muse, mutect2
- LAT2 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as COSV99305873; called by muse, mutect2, varscan2
- LATS2 | c.2186T>C p.V729A | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231619, COSV66880185; called by muse, mutect2, varscan2
- LCT | c.4037G>T p.R1346L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51552593, COSV99929880; called by muse, mutect2
- LINGO1 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100796447, COSV62436236; called by muse, mutect2, varscan2
- LIPG | c.839T>A p.L280H | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724561; called by muse, mutect2, varscan2
- LNPEP | c.1106T>G p.L369R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV99183564; called by muse, mutect2, varscan2
- LPCAT1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV99359133; called by muse, mutect2, varscan2
- LRBA | c.7943A>T p.E2648V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100841880; called by muse, mutect2, varscan2
- LRP4 | c.2642G>A p.S881N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101066724; called by muse, mutect2, varscan2
- LRRC14B | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1040840672, COSV99360632; called by mutect2, varscan2
- LRRN3 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV57820571; called by mutect2, varscan2
- MACF1 | c.2680C>A p.L894I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100485353; called by muse, mutect2, varscan2
- MAGEA8 | c.759G>T p.W253C | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV54063884; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK8IP1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs768339614, COSV99571588; called by muse, mutect2, varscan2
- MARS2 | c.1522A>T p.T508S | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99986623; called by muse, mutect2, varscan2
- MATN2 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99646615; called by muse, mutect2, varscan2
- MCM7 | c.1739A>G p.Y580C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100385040; called by muse, mutect2
- MCM7 | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100385041; called by muse, mutect2, varscan2
- MDM1 | c.1007T>G p.V336G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100291946, COSV57447522; called by muse, mutect2, varscan2
- MEGF6 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1314808564, COSV100742195; called by muse, mutect2, varscan2
- MEIS2 | c.150C>G p.H50Q (on ENST00000561208 / NM_170675.5; = p.H37Q on NM_002399.3) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.162); catalogued as COSV99576755; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MIA2 | c.1132T>G p.F378V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99696821; called by muse, mutect2, varscan2
- MICAL2 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99817899; called by muse, mutect2, varscan2
- MID1 | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV100452551; called by muse, mutect2, varscan2
- MIGA1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.491); catalogued as COSV66224036; called by muse, mutect2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | catalogued as rs751180035; called by mutect2, varscan2
- MLH1 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99212519; called by muse, mutect2, varscan2
- MMRN1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99307398; called by muse, mutect2, varscan2
- MORN5 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs781423001, COSV65648926; called by muse, mutect2, varscan2
- MOS | c.409A>C p.I137L | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV100322899, COSV61336655; called by muse, mutect2
- MPC1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs753601697, COSV59133456, COSV59133844; called by muse, mutect2, varscan2
- MSI2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs772529843; called by muse, mutect2, varscan2
- MTNR1A | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV100208257; called by muse, mutect2, varscan2
- MTRR | c.577G>T p.A193S (on ENST00000264668; = p.A166S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as rs114253881, COSV52941514; called by muse, mutect2, varscan2
- MUC5B | c.6856G>A p.A2286T | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV71594911; called by muse, varscan2
- MUC5B | c.11052_11054del p.S3685del | In Frame Del (DEL) | VAF 91/233 reads (39%) | catalogued as rs1175863118; called by pindel, varscan2
- MXRA5 | c.6044C>T p.A2015V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.695); catalogued as COSV99475755; called by muse, mutect2
- MYADM | c.385T>A p.S129T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV100425122, COSV61238912; called by muse, mutect2, varscan2
- MYCBP2 | c.11990A>G p.Q3997R (on ENST00000357337; = p.Q4035R on NM_015057.5) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100630934; called by muse, mutect2, varscan2
- MYCBP2 | c.5913G>T p.Q1971H (on ENST00000357337; = p.Q2009H on NM_015057.5) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.965); catalogued as COSV100630940; called by muse, mutect2, varscan2
- MYCBP2 | c.4091A>C p.E1364A (on ENST00000357337; = p.E1402A on NM_015057.5) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100630941; called by muse, mutect2, varscan2
- MYO15A | c.569T>C p.F190S | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV99233502; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1A | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs769645609, COSV100271061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCOR2 | c.5540G>A p.R1847H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs753590635, COSV100657606; called by muse, mutect2, varscan2
- NCOR2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1372001604, COSV62299970; called by muse, mutect2, varscan2
- NEB | c.7060A>T p.K2354* | Nonsense Mutation (SNP) | VAF 20/248 reads (8%) | catalogued as COSV50854548, COSV99425076; called by muse, mutect2
- NEIL2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs772930057, COSV99462342; called by muse, mutect2, varscan2
- NEK1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101455742; called by muse, mutect2, varscan2
- NEK10 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1559469059, COSV100412073; called by muse, mutect2
- NEXMIF | c.1268A>T p.N423I | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs781494679, COSV99281188; called by muse, mutect2, varscan2
- NFE2L1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs763812508, COSV100671634; called by muse, mutect2, varscan2
- NFKB2 | c.1587G>T p.T529= | Splice Region (SNP) | VAF 24/46 reads (52%) | catalogued as COSV50043332, COSV99192976; called by muse, mutect2, varscan2
- NIN | c.5222C>T p.A1741V (on ENST00000382041 / NM_182946.1; = p.A1028V on NM_016350.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs762668291, COSV55397086, COSV55397898; called by muse, mutect2, varscan2
- NIPBL | c.3622A>T p.N1208Y | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as COSV99241352; called by muse, mutect2, varscan2
- NKTR | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs151022212; called by muse, mutect2, varscan2
- NLGN4X | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.815); catalogued as COSV52023051, COSV99322717; called by muse, mutect2, varscan2
- NLRC4 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV100707445; called by muse, mutect2
- NMNAT3 | c.120G>T p.Q40H (on ENST00000296202 / NM_001320512.1; = p.Q3H on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.817); catalogued as rs1207627131, COSV99951859; called by muse, mutect2, varscan2
- NOTCH2 | c.1817A>G p.D606G | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as COSV99865221; called by muse, mutect2, varscan2
- NPAT | c.3293T>C p.L1098P | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99586188; called by muse, mutect2
- NPY2R | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV100279805; called by muse, mutect2, varscan2
- NRP1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99589144; called by muse, mutect2
- NRP1 | c.422T>C p.F141S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as COSV99589148; called by muse, mutect2, varscan2
- NUDT11 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV101047081; called by muse, mutect2
- NUP133 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV99773152; called by muse, mutect2, varscan2
- NUP205 | c.3526A>G p.T1176A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs895892622, COSV53660702, COSV99607235; called by muse, mutect2, varscan2
- NWD1 | c.2523C>A p.C841* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100343102; called by muse, mutect2, varscan2
- NXPE1 | c.1409C>T p.A470V (on ENST00000424269; = p.A328V on NM_152315.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs867994414, COSV99320670; called by muse, mutect2, varscan2
- OAS3 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99966410; called by muse, mutect2
- OAZ3 | c.303G>A p.S101= | Splice Region (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100162582; called by muse, mutect2, varscan2
- OIT3 | c.1484G>A p.C495Y | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100468150; called by muse, mutect2
- OLFML2B | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs751215866, COSV99668624; called by muse, mutect2, varscan2
- OR10G2 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101606961; called by muse, mutect2, varscan2
- OR10Z1 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100778924, COSV100779040; called by muse, mutect2, varscan2
- OR1J4 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as COSV100534299; called by muse, mutect2, varscan2
- OR1L3 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1564233055, COSV100506264; called by muse, mutect2
- OR1L3 | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.598); catalogued as COSV100506265; called by muse, mutect2, varscan2
- OR1N2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV101031406, COSV101031429; called by muse, mutect2, varscan2
- OR2M4 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.292); catalogued as COSV100141352, COSV60709775, COSV60709879; called by muse, mutect2, varscan2
- OR2M7 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV100522605; called by muse, mutect2, varscan2
- OR4A15 | c.422T>A p.L141H | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV100124213; called by muse, mutect2
- OR4A5 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); catalogued as rs138866955; called by muse, mutect2, varscan2
- OR4C12 | c.294A>C p.Q98H | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100078593, COSV58860343; called by muse, mutect2, varscan2
- OR4X2 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV100183272; called by muse, mutect2
- OR56B4 | c.649A>G p.M217V | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100337673; called by muse, mutect2, varscan2
- OR5M10 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101595875, COSV101595905; called by muse, mutect2, varscan2
- OR6C76 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.28); catalogued as COSV60390133; called by muse, mutect2
- OR8B3 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV100660410, COSV63541358; called by muse, mutect2, varscan2
- OR8H3 | c.580A>T p.N194Y | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.44); catalogued as COSV100539052; called by muse, mutect2
- PALLD | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99825173; called by muse, mutect2, varscan2
- PAPOLA | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV53483221; called by muse, mutect2
- PAXX | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100860436; called by muse, mutect2, varscan2
- PBRM1 | c.2932G>A p.V978I | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs375687372; called by muse, mutect2
- PCDHA10 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as COSV100251875; called by muse, mutect2
- PCDHGA12 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.1); catalogued as COSV99341095; called by muse, mutect2
- PCDHGA5 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.314); catalogued as rs1357530807, COSV54045565; called by muse, mutect2, varscan2
- PCDHGA5 | c.2236G>A p.V746I | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs181587578, COSV99541788; called by muse, mutect2, varscan2
- PDE12 | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100239907; called by muse, mutect2, varscan2
- PDE8B | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318900892, COSV99366772; called by muse, mutect2, varscan2
- PEAR1 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs200829847, COSV99441815; called by muse, mutect2, varscan2
- PEG3 | c.4121T>C p.V1374A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV99689526; called by muse, mutect2, varscan2
- PEX5 | c.1894C>A p.L632I (on ENST00000420616; = p.L624I on NM_000319.5) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.32); catalogued as COSV99871082; called by muse, mutect2, varscan2
- PFKP | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs757633268, COSV101126931, COSV66894933; called by muse, mutect2, varscan2
- PHF24 | c.703del p.D235Tfs*6 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as COSV54275977; called by mutect2, pindel, varscan2
- PHKA2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV66053456; called by muse, mutect2, varscan2
- PHLDB1 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 24/121 reads (20%) | catalogued as rs199607223; called by muse, mutect2, varscan2
- PIGZ | c.1467del p.T490Lfs*10 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs759867499; called by pindel, varscan2
- PIK3R4 | c.2250G>C p.K750N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.125); catalogued as COSV63241305; called by muse, mutect2, varscan2
- PIKFYVE | c.5920C>A p.L1974M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100010643; called by muse, mutect2, varscan2
- PKDCC | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99684906; called by muse, mutect2
- PKP3 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100520902; called by muse, mutect2
- PLEC | c.6428C>T p.A2143V (on ENST00000322810 / NM_201380.4; = p.A2033V on NM_000445.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs376537341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLPPR2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs755263429, COSV99264584; called by mutect2, varscan2
- PLTP | c.191_193del p.N64del | In Frame Del (DEL) | VAF 18/124 reads (15%) | catalogued as rs761925325; called by pindel, varscan2
- PLXDC1 | c.1346G>A p.G449D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.203); catalogued as COSV100195567; called by muse, mutect2, varscan2
- PLXNC1 | c.1259A>C p.K420T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV99313435; called by muse, mutect2, varscan2
- PMFBP1 | c.2140G>A p.A714T (on ENST00000537465; = p.A709T on NM_031293.3) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99401178; called by muse, mutect2, varscan2
- PNN | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs1004595541, COSV53767572; called by muse, mutect2
- POF1B | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99426979, COSV99427051; called by muse, mutect2, varscan2
- POF1B | c.462A>T p.R154S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV99426982; called by muse, mutect2, varscan2
- PPEF1 | c.1442T>C p.V481A | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100583889; called by muse, mutect2, varscan2
- PPM1J | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs1485479499, COSV58551811; called by muse, mutect2
- PPP1R12B | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100407875; called by muse, mutect2, varscan2
- PPP1R15B | c.249T>G p.I83M | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.087); catalogued as COSV100916351; called by muse, mutect2, varscan2
- PPP1R16B | c.1427G>A p.S476N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100239676; called by muse, mutect2
- PPP2R1B | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV100232258; called by muse, mutect2
- PPP2R2C | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100066903; called by muse, mutect2, varscan2
- PPTC7 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV100845719; called by muse, mutect2, varscan2
- PRAMEF12 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs368330234; called by muse, mutect2, varscan2
- PRIM2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99227987; called by muse, mutect2, varscan2
- PRKCB | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV57793166; called by muse, mutect2, varscan2
- PRPF4 | c.701C>G p.S234C (on ENST00000374198 / NM_001322267.2; = p.S235C on NM_004697.5) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1487420666, COSV100950730; called by muse, mutect2, varscan2
- PRPS2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs139958695, COSV66179531; called by muse, mutect2, varscan2
- PRR35 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV99216239; called by mutect2, varscan2
- PRRT1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs894672075, COSV99278397, COSV99278548; called by muse, mutect2, varscan2
- PSG3 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs376695264; called by muse, mutect2, varscan2
- PTAFR | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100544403; called by muse, mutect2, varscan2
- PTCH2 | c.171A>C p.K57N | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100942184; called by muse, mutect2
- PTPRT | c.1886A>C p.K629T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100628599; called by muse, mutect2, varscan2
- PXDN | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs767012980, COSV99414118; called by muse, mutect2, varscan2
- PXDNL | c.2426T>G p.F809C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100684764; called by muse, mutect2, varscan2
- PXN | c.1480C>A p.L494M (on ENST00000228307 / NM_001080855.3; = p.L460M on NM_002859.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV57219464; called by muse, mutect2
- RAD51AP2 | c.3419T>G p.I1140S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV101208374; called by muse, mutect2
- RAD54L2 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.372); catalogued as COSV99621531; called by muse, mutect2
- RAI1 | c.4811G>A p.R1604Q | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs773995975, COSV55399643; called by muse, mutect2, varscan2
- RASGRP2 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.105); catalogued as COSV100818296; called by muse, mutect2, varscan2
- RBM19 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99926399; called by muse, mutect2, varscan2
- RBM4 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV59517921, COSV59518087; called by muse, mutect2
- RBSN | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV99515383; called by muse, mutect2, varscan2
- RCCD1 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV101263227; called by muse, mutect2, varscan2
- REV1 | c.1514G>T p.R505M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99301158; called by muse, mutect2, varscan2
- REX1BD | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100679010; called by mutect2, varscan2
- RFC2 | c.1048G>A p.A350T (on ENST00000055077 / NM_181471.3; = p.A316T on NM_002914.4) | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99277994; called by muse, mutect2
- RFT1 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99965498; called by muse, mutect2
- RGS5 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100009183, COSV58352978; called by muse, mutect2, varscan2
- RGS5 | c.161C>A p.S54* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100009184, COSV58351693; called by muse, mutect2, varscan2
- RGS9 | c.1402A>G p.T468A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99287685; called by muse, mutect2, varscan2
- RHCE | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV99604246; called by muse, mutect2, varscan2
- RHO | c.766A>C p.I256L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99960698; called by muse, mutect2, varscan2
- RLF | c.3221del p.N1074Tfs*3 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as COSV65653509; called by mutect2, pindel, varscan2
- RNASEH1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100177197; called by muse, mutect2, varscan2
- RNF213 | c.7979C>T p.A2660V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs748937258, COSV100301048; called by muse, mutect2, varscan2
- RNF215 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99306622; called by muse, mutect2, varscan2
- RNF40 | c.1621A>C p.S541R | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs1025593959, COSV100222201; called by muse, mutect2
- ROBO4 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100127691; called by muse, mutect2, varscan2
- ROR1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.295); catalogued as COSV100935387, COSV100935398, COSV64286772; called by muse, mutect2, varscan2
- ROR2 | c.1651A>G p.M551V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100995919; called by muse, mutect2, varscan2
- RPGRIP1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV99251335; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA6 | c.2238A>C p.*746Yext*6 | Nonstop Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99425013; called by muse, mutect2, varscan2
- RPS6KB1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99847614; called by muse, mutect2, varscan2
- RSAD2 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs751555584, COSV65908654; called by muse, mutect2, varscan2
- RUNX1T1 | c.169C>T p.P57S (on ENST00000265814 / NM_001198628.1; = p.P30S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs759112769, COSV99753112; called by muse, mutect2, varscan2
- RYR1 | c.7778G>C p.R2593P | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100616227, COSV62088247; called by muse, mutect2, varscan2
- SAFB | c.1810T>A p.S604T | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV99412979; called by muse, mutect2, varscan2
- SAMM50 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs770409380, COSV100601305, COSV63109605; called by muse, mutect2, varscan2
- SART3 | c.1847C>T p.A616V (on ENST00000228284; = p.A598V on NM_014706.4) | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV99934218; called by muse, mutect2
- SCN7A | c.4229G>T p.G1410V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101313287; called by muse, mutect2
- SDK2 | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1258292112, COSV66180615; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SERPINA7 | c.1037T>A p.L346H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59666364; called by muse, mutect2, varscan2
- SERPINE1 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV56171030; called by muse, mutect2
- SERPINF2 | c.1112A>G p.Q371R | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV100132011; called by muse, mutect2, varscan2
- SETBP1 | c.4333A>C p.T1445P | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56314146, COSV99953899; called by muse, mutect2, varscan2
- SHANK2 | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53607470, COSV99574976; called by muse, mutect2, varscan2
- SHMT2 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100197239, COSV61075081; called by muse, mutect2, varscan2
- SHQ1 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as rs777239706, COSV57765544; called by muse, mutect2, varscan2
- SHTN1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99599166; called by muse, mutect2, varscan2
- SIK3 | c.2617C>T p.R873C (on ENST00000445177 / NM_001366686.2; = p.R831C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs768087803, COSV52608420; called by muse, mutect2, varscan2
- SLC12A1 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.037); catalogued as rs376723001; called by muse, mutect2, varscan2
- SLC13A3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs752990690, COSV51712856; called by muse, mutect2, varscan2
- SLC1A2 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99554745; called by mutect2, varscan2
- SLC25A18 | c.411C>T p.A137= | Splice Region (SNP) | VAF 49/163 reads (30%) | catalogued as rs575576520, COSV99494360; called by muse, mutect2, varscan2
- SLC39A12 | c.1859G>A p.G620D (on ENST00000377369 / NM_001145195.2; = p.G583D on NM_152725.3) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101070084; called by muse, mutect2, varscan2
- SLC46A3 | c.816del p.F272Lfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs768002987; called by mutect2, pindel, varscan2
- SLC4A11 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.192); catalogued as rs141426484; called by muse, mutect2, varscan2
- SLC6A18 | c.1435A>G p.N479D | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV99722462; called by muse, mutect2, varscan2
- SLC7A6 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV99546689; called by muse, mutect2
- SLC8B1 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99176767; called by muse, mutect2, varscan2
- SLFN5 | c.562A>G p.N188D | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV100249733; called by muse, mutect2
- SMARCC2 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57217668; called by muse, mutect2
- SMC1B | c.2356G>A p.V786M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs774065033, COSV62528872; called by muse, mutect2, varscan2
- SMCR8 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as rs769649612, COSV68810782; called by mutect2, varscan2
- SMOC1 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV100734693; called by muse, mutect2
- SND1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 5/69 reads (7%) | catalogued as COSV100690696; called by muse, mutect2
- SNX11 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759226849, COSV100821773; called by muse, mutect2, varscan2
- SOX17 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99810709; called by muse, mutect2, varscan2
- SPIN2A | c.346T>A p.S116T | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV100888064; called by muse, mutect2, varscan2
- SPRY3 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.369); catalogued as rs200736621, COSV57143605; called by muse, mutect2, varscan2
- SPTA1 | c.2464+2T>G p.X822_splice | Splice Site (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100935173; called by muse, mutect2
- SPTLC3 | c.1256T>C p.M419T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs753031055, COSV100983228; called by muse, mutect2, varscan2
- SRP9 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV100504899; called by muse, mutect2, varscan2
- SSBP2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100283854; called by muse, mutect2, varscan2
- SSUH2 | c.918C>T p.R306= | Splice Region (SNP) | VAF 4/48 reads (8%) | catalogued as rs1471494711; called by muse, mutect2
- ST3GAL1 | c.757A>G p.K253E | Missense Mutation (SNP) | VAF 11/170 reads (6%) | PolyPhen probably damaging (0.93); catalogued as COSV100172286; called by muse, mutect2
- STRIP1 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100873974; called by muse, mutect2
- STS | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.384); catalogued as rs1312714145, COSV99481426; called by muse, mutect2
- SUPT6H | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112576; called by muse, mutect2, varscan2
- SYNE2 | c.18580G>T p.E6194* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | catalogued as COSV100648069; called by muse, mutect2
- SYNPO | c.1481del p.G494Afs*11 (on ENST00000394243 / NM_001166208.2; = p.G250Afs*11 on NM_007286.6) | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as COSV56939890; called by mutect2, pindel, varscan2
- SYT3 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs368534907; called by muse, mutect2, varscan2
- SYVN1 | c.1250C>G p.P417R (on ENST00000377190 / NM_172230.3; = p.P416R on NM_032431.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV99589169; called by muse, mutect2, varscan2
- TAB1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99336144; called by muse, mutect2, varscan2
- TAF7L | c.719dup p.V241Gfs*3 | Frame Shift Ins (INS) | VAF 50/118 reads (42%) | catalogued as COSV61258097; called by mutect2, varscan2
- TBC1D32 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51552412; called by muse, mutect2, varscan2
- TCF23 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99940365; called by muse, mutect2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TECPR2 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100850095; called by muse, mutect2, varscan2
- TECR | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1189016830, COSV53108131; called by muse, mutect2, varscan2
- TET3 | c.1085C>G p.A362G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99996460, COSV99996683; called by muse, mutect2, varscan2
- TEX15 | c.2916G>T p.K972N (on ENST00000256246; = p.K1355N on NM_001350162.2) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99821686; called by muse, mutect2, varscan2
- TEX29 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV99365981, COSV99366185; called by muse, mutect2, varscan2
- TGFBRAP1 | c.521C>A p.A174D | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as COSV99305257; called by muse, mutect2, varscan2
- THADA | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs758393859, COSV57685752; called by muse, mutect2, varscan2
- THAP9 | c.1383A>G p.I461M | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV100155903; called by muse, mutect2, varscan2
- TICRR | c.3123_3124del p.R1042Sfs*8 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs756521772; called by mutect2, pindel, varscan2
- TIMM44 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99564178; called by muse, mutect2, varscan2
- TLE1 | c.670A>C p.I224L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100916325; called by muse, mutect2, varscan2
- TLN2 | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV100169493; called by muse, mutect2, varscan2
- TM9SF2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs762293864, COSV100899731; called by muse, mutect2
- TMEFF2 | c.908del p.K303Rfs*19 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs1553506636, COSV55829678; called by mutect2, pindel, varscan2
- TMEM107 | c.297C>A p.F99L (on ENST00000437139 / NM_183065.4; = p.F105L on NM_032354.5) | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV100328764; called by muse, mutect2, varscan2
- TMEM135 | c.502T>G p.F168V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100449872; called by muse, mutect2, varscan2
- TMEM175 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs201969822; called by muse, mutect2, varscan2
- TMEM52B | c.158C>T p.A53V (on ENST00000381923 / NM_001079815.1; = p.A33V on NM_153022.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.285); catalogued as rs1177507184, COSV53728107; called by muse, mutect2, varscan2
- TMEM74 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV99865755; called by muse, mutect2, varscan2
- TNS3 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1051570050, COSV100235882; called by muse, mutect2, varscan2
- TOP1 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100793895; called by muse, mutect2, varscan2
- TP53I13 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99838293; called by muse, mutect2, varscan2
- TPCN2 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53726805, COSV99593731; called by muse, mutect2
- TRA2B | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV52024601; called by muse, mutect2, varscan2
- TRAC | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs61740301; called by muse, mutect2, varscan2
- TRIM48 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV101338305, COSV70162579; called by muse, mutect2, varscan2
- TRPM1 | c.2576T>C p.L859P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99856206; called by muse, mutect2, varscan2
- TRRAP | c.7382T>G p.V2461G (on ENST00000359863 / NM_001244580.1; = p.V2443G on NM_003496.3) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100722656; called by muse, mutect2, varscan2
- TSC22D1 | c.3014T>G p.V1005G (on ENST00000458659 / NM_183422.4; = p.V76G on NM_006022.4) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV54925804, COSV99817943; called by muse, mutect2, varscan2
- TSPAN14 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100540327; called by muse, mutect2, varscan2
- TTC14 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99932160; called by muse, mutect2
- TTC26 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100571076; called by muse, mutect2, varscan2
- TTL | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as COSV99271408, COSV99271653; called by muse, mutect2, varscan2
- TTL | c.1039T>A p.C347S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV99271412; called by muse, mutect2
- TTLL3 | c.978A>C p.K326N | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV100047668; called by muse, mutect2
- TTN | c.46404G>T p.K15468N (on ENST00000591111; = p.K8044N on NM_003319.4) | Missense Mutation (SNP) | VAF 44/130 reads (34%) | PolyPhen probably damaging (0.997); catalogued as COSV100619972; called by muse, mutect2, varscan2
- TTN | c.41425A>G p.K13809E (on ENST00000591111; = p.K6385E on NM_003319.4) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | PolyPhen possibly damaging (0.475); catalogued as COSV100619974; called by muse, mutect2, varscan2
- TTN | c.41309_41311del p.S13770del (on ENST00000591111; = p.S6346del on NM_003319.4) | In Frame Del (DEL) | VAF 35/79 reads (44%) | catalogued as rs750724970; called by mutect2, pindel, varscan2
- TTN | c.18195A>C p.Q6065H (on ENST00000591111; = p.Q5138H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | PolyPhen probably damaging (0.964); catalogued as rs1314783097, COSV59971553; called by muse, mutect2, varscan2
- TUBE1 | c.526T>A p.S176T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as COSV100898303; called by muse, mutect2, varscan2
- TUBGCP6 | c.4874G>A p.S1625N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99955885; called by muse, mutect2, varscan2
- UBA3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100734725; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | catalogued as rs763652408; called by mutect2, varscan2
- USP40 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.732); catalogued as rs548513246, COSV99295549; called by muse, varscan2
- UTP14C | c.1062_1064del p.L355del | In Frame Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs758604982; called by mutect2, pindel, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 17/135 reads (13%) | catalogued as rs761528888; called by mutect2, varscan2
- UTP25 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101504751; called by muse, mutect2, varscan2
- UTRN | c.7177G>A p.A2393T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100840071; called by muse, mutect2
- VCPIP1 | c.2087G>A p.G696E | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100125701; called by muse, mutect2, varscan2
- VWCE | c.1564A>G p.T522A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100075985; called by muse, mutect2
- VWCE | c.1466dup p.Q490Tfs*30 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | catalogued as rs753714493; called by mutect2, varscan2
- WDR5B | c.713A>T p.D238V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99216402; called by muse, mutect2, varscan2
- WNT6 | c.521A>G p.D174G | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV52110941; called by muse, mutect2
- WSB2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs550650687, COSV59573597; called by muse, mutect2, varscan2
- XK | c.397C>G p.R133G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM004084, COSV101064739; called by muse, mutect2, varscan2
- XPR1 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 23/144 reads (16%) | catalogued as COSV62560922; called by muse, mutect2, varscan2
- ZBTB14 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100813475; called by muse, mutect2, varscan2
- ZC3H10 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs531554160, COSV57768272; called by muse, mutect2, varscan2
- ZDHHC24 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs747432462, COSV60080186; called by muse, mutect2, varscan2
- ZFP28 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs754718719, COSV56734716; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs563751025; called by mutect2, varscan2
- ZFP64 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs770091651, COSV53803802; called by muse, mutect2, varscan2
- ZFP69 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as rs752437339, COSV65529111; called by muse, mutect2, varscan2
- ZFYVE27 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as rs1202539388, COSV100519245, COSV100519334; called by muse, mutect2
- ZGRF1 | c.5775G>T p.Q1925H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101500634; called by muse, mutect2, varscan2
- ZMYM3 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.981); catalogued as rs1276761120, COSV58736675; called by muse, mutect2, varscan2
- ZNF205 | c.1403_1404dup p.T469Afs*69 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | catalogued as rs1567178958; called by mutect2, pindel, varscan2
- ZNF215 | c.667A>C p.K223Q | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.273); catalogued as COSV99549761; called by muse, mutect2, varscan2
- ZNF277 | c.145A>C p.T49P | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV100702487; called by muse, mutect2
- ZNF41 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as COSV100492156; called by muse, mutect2, varscan2
- ZNF518B | c.2972G>A p.R991H | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1314132671, COSV58722431; called by muse, mutect2
- ZNF546 | c.1821A>C p.K607N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100713502, COSV61257872; called by muse, mutect2
- ZNF569 | c.783A>C p.Q261H | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.291); catalogued as COSV100386539; called by muse, mutect2, varscan2
- ZNF654 | c.2486C>A p.P829Q | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV100525815, COSV58805832; called by muse, mutect2
- ZNF782 | c.1680A>C p.K560N | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56653187; called by muse, mutect2, varscan2
- ZSCAN9 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs767840402, COSV52849641, COSV99356507; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 17/120 reads (14%) | called by mutect2, pindel, varscan2
- ABCA2 | c.5028_5032del p.Q1676Hfs*34 (on ENST00000614293; = p.Q1646Hfs*34 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel
- ADAD1 | c.1493dup p.F499Ifs*2 | Frame Shift Ins (INS) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- ATXN10 | c.517del p.I173Lfs*7 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- C1GALT1C1L | c.30del p.F10Lfs*13 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel
- CLCN4 | c.369del p.F123Lfs*18 | Frame Shift Del (DEL) | VAF 30/159 reads (19%) | called by pindel, varscan2
- CLHC1 | c.1417del p.Q473Kfs*4 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- COL4A4 | c.1169del p.P390Qfs*14 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.035); called by muse, mutect2
- CSGALNACT2 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CSMD3 | c.7457_7463del p.W2486Ffs*13 (on ENST00000297405 / NM_001363185.1; = p.W2382Ffs*13 on NM_052900.3) | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- CUX1 | c.1318del p.E440Sfs*17 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, varscan2
- DYRK3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2
- EIF2AK1 | c.852del p.T285Pfs*21 | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | called by mutect2, pindel
- EIF2B5 | c.1571del p.X524_splice (on ENST00000647909; = p.X516_splice on NM_003907.3) | Splice Site (DEL) | VAF 10/14 reads (71%) | called by mutect2, varscan2
- ETAA1 | c.2704del p.R902Dfs*17 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by mutect2, pindel
- FARP1 | c.1063_1065del p.G355del | In Frame Del (DEL) | VAF 25/233 reads (11%) | called by pindel, varscan2
- FBXW7 | c.1445del p.T482Ifs*16 (on ENST00000281708 / NM_001349798.2; = p.T402Ifs*16 on NM_018315.5) | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel*, varscan2
- GOSR2 | c.125del p.P42Lfs*14 (on ENST00000393456 / NM_001321134.1; = p.P60Lfs*14 on NM_004287.5) | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- HJV | c.889T>C p.S297P (on ENST00000336751 / NM_213653.4; = p.S184P on NM_145277.5) | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- ICAM2 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- IFI44 | c.781_783del p.G261del | In Frame Del (DEL) | VAF 14/60 reads (23%) | called by pindel, varscan2
- ISY1-RAB43 | c.168dup p.V57Sfs*11 | Frame Shift Ins (INS) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- KDM4B | c.1972_1973del p.L658Afs*42 | Frame Shift Del (DEL) | VAF 40/75 reads (53%) | called by pindel, varscan2
- KIF18B | c.378del p.G127Afs*5 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel, varscan2
- KMT2E | c.1657del p.T553Lfs*7 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- KRT9 | c.613_615del p.Y205del | In Frame Del (DEL) | VAF 23/134 reads (17%) | called by pindel, varscan2
- KRTAP13-3 | c.53_56del p.Y18Cfs*75 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by pindel, varscan2
- LBP | c.7del p.A3? | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, varscan2
- LILRA2 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGI1 | c.1727dup p.L576Ffs*3 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- MAP4K1 | c.1666_1667del p.S556Rfs*10 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | called by pindel, varscan2
- MSN | c.789del p.A264Pfs*42 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- NBPF1 | c.1377dup p.R460Qfs*7 | Frame Shift Ins (INS) | VAF 53/460 reads (12%) | called by mutect2, varscan2
- NEUROD1 | c.616del p.H206Tfs*56 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- PATJ | c.1520del p.N507Mfs*7 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- PCLO | c.10235del p.K3412Rfs*19 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- PDZD7 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- PIP4K2A | c.1103dup p.K369Efs*10 | Frame Shift Ins (INS) | VAF 12/126 reads (10%) | called by mutect2, pindel
- PLEC | c.4454A>T p.E1485V (on ENST00000322810 / NM_201380.4; = p.E1375V on NM_000445.5) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PTAR1 | c.762_763dup p.S255Tfs*4 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- PTCHD3 | c.1366del p.V456Sfs*7 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel
- PTPN4 | c.963dup p.A322Cfs*17 | Frame Shift Ins (INS) | VAF 15/95 reads (16%) | called by mutect2, varscan2
- RIMS1 | c.1873del p.M625* | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- RIPK4 | c.2286dup p.H763Afs*15 (on ENST00000352483; = p.H715Afs*15 on NM_020639.3) | Frame Shift Ins (INS) | VAF 39/70 reads (56%) | called by mutect2, pindel, varscan2
- RUSC2 | c.886del p.R296Vfs*132 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- SEPTIN9 | c.1400C>T p.S467F (on ENST00000427177 / NM_001113491.2; = p.S449F on NM_006640.4) | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2
- SH3BP4 | c.1991_2005del p.T664_Q668del | In Frame Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- SKIL | c.83del p.P28Qfs*5 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- SLC11A2 | c.720del p.F240Lfs*19 (on ENST00000394904 / NM_001379455.1; = p.F211Lfs*19 on NM_000617.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- SLC39A9 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STEAP3 | c.1246A>G p.T416A | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SYNE1 | c.25785del p.M8596Cfs*3 (on ENST00000367255 / NM_182961.4; = p.M8548Cfs*3 on NM_033071.3) | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- TOR1AIP2 | c.211_212del p.E71Kfs*4 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- UGP2 | c.520del p.I174Yfs*10 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- VWA1 | c.462dup p.M155Hfs*43 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- WDFY3 | c.7659del p.L2554Sfs*11 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- ZIC4 | c.611T>G p.F204C | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF155 | c.1446del p.K482Nfs*44 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- ZNF329 | c.911dup p.L304Ffs*13 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ZNF440 | c.130+2del p.X44_splice | Splice Site (DEL) | VAF 37/60 reads (62%) | called by mutect2, pindel, varscan2
- ZSCAN26 | c.847C>T p.Q283* (on ENST00000623276 / NM_001111039.2; = p.Q149* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- ADA2 | c.1044C>A p.G348= (on ENST00000262607; = p.G107= on NM_177405.3) | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV99376228; called by muse, varscan2
- ADAMTS17 | c.2865C>T p.C955= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs746354760, COSV51475556, COSV99170777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB2 | c.597C>T p.H199= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101186897, COSV101187053; called by muse, mutect2, varscan2
- AJM1 | c.1017G>A p.P339= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1194601883, COSV56033183; called by muse, mutect2, varscan2
- AKAP14 | c.96C>T p.Y32= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs1317723089, COSV100538345; called by muse, mutect2, varscan2
- ANKRD16 | c.444C>T p.G148= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs920947153, COSV51948002; called by muse, mutect2, varscan2
- ARAP1 | c.870C>T p.G290= (on ENST00000393609 / NM_001040118.2; = p.G45= on NM_015242.4) | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs1268307819, COSV61990096; called by muse, mutect2, varscan2
- ARHGAP31 | c.3288G>T p.G1096= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as COSV99957347; called by mutect2, varscan2
- ASGR2 | c.618G>A p.Q206= | Silent (SNP) | VAF 43/62 reads (69%) | catalogued as COSV99643083; called by muse, mutect2, varscan2
- ATPAF1 | c.282T>G p.A94= (on ENST00000574428; = p.A117= on NM_022745.4) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100236275; called by muse, mutect2
- ATXN2L | c.2769G>A p.P923= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs549666349, COSV100294218, COSV57367928; called by muse, mutect2, varscan2
- BCL6B | c.78C>T p.G26= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs770426680, COSV99546752; called by muse, mutect2, varscan2
- BNC1 | c.2025G>A p.Q675= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV100597316; called by muse, mutect2, varscan2
- BRD2 | c.1473T>C p.S491= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100875747; called by muse, mutect2, varscan2
- BTBD7 | c.117C>T p.C39= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs765663061, COSV54135903; called by muse, mutect2, varscan2
- BTK | c.558G>A p.K186= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as CX056898, CX972731; called by muse, mutect2
- C3 | c.1551G>A p.L517= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99836892; called by muse, mutect2, varscan2
- CACNA1B | c.4248C>T p.I1416= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as COSV99498393; called by muse, mutect2, varscan2
- CACNA1H | c.4044G>A p.V1348= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1320632801, COSV100673135; called by muse, mutect2, varscan2
- CAMSAP2 | c.3924G>A p.T1308= (on ENST00000236925 / NM_001297707.2; = p.T1297= on NM_203459.3) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs570434143, COSV99373672; called by muse, mutect2, varscan2
- CAVIN4 | c.573C>T p.G191= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100293318; called by muse, mutect2, varscan2
- CBL | c.825C>T p.D275= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs751768529, COSV50635379; called by muse, mutect2, varscan2
- CCDC71 | c.648A>G p.S216= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV100422391; called by muse, mutect2, varscan2
- CCDC74A | c.414C>T p.G138= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV99723791; called by muse, mutect2
- CCDC74B | c.498C>T p.S166= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100134464; called by muse, mutect2, varscan2
- CCL25 | c.441T>C p.N147= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99495204; called by muse, mutect2, varscan2
- CDCA7L | c.267G>A p.Q89= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs779372905, COSV100651146, COSV62258105; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2127C>T p.D709= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs902152960, COSV62573624; called by muse, mutect2, varscan2
- CDR1 | c.471C>G p.P157= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV100983430, COSV100983440, COSV65163895; called by muse, mutect2
- CFAP65 | c.1947G>T p.P649= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100445424; called by muse, mutect2
- CLEC14A | c.969C>T p.V323= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as rs772963880, COSV60563346; called by muse, mutect2, varscan2
- CLSTN1 | c.2841C>T p.S947= (on ENST00000377298 / NM_001009566.3; = p.S937= on NM_014944.4) | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs777490716, COSV100740295; called by muse, mutect2, varscan2
- CMYA5 | c.186G>A p.Q62= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- COL19A1 | c.609G>A p.V203= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100506777, COSV59572006; called by muse, varscan2
- COL1A1 | c.2283C>T p.G761= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs759665341, COSV56802684, COSV56808314; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL23A1 | c.570A>G p.G190= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101179283; called by mutect2, varscan2
- CORT | c.78C>T p.G26= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100259228; called by mutect2, varscan2
- CSH2 | c.30C>T p.L10= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs1249359787, COSV100400272; called by muse, mutect2, varscan2
- CSPG4 | c.915G>A p.T305= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs772770210, COSV57894559; called by mutect2, varscan2
- CYFIP1 | c.1317G>A p.T439= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs765112283; called by muse, mutect2, varscan2
- DEFB135 | c.78C>T p.P26= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV101198556; called by muse, mutect2, varscan2
- DISP1 | c.3990G>A p.T1330= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs370266646, COSV99451432; called by muse, mutect2, varscan2
- DNAH6 | c.2304A>C p.T768= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV99407518; called by muse, mutect2, varscan2
- DNALI1 | c.508C>T p.L170= (on ENST00000296218; = p.L148= on NM_003462.5) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99953675; called by muse, mutect2, varscan2
- DOCK3 | c.5883C>T p.C1961= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV56521563; called by muse, mutect2, varscan2
- DOCK4 | c.18G>A p.E6= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100702486; called by muse, mutect2
- DOK1 | c.669C>T p.R223= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99284124; called by muse, mutect2
- DSCAML1 | c.2832G>A p.V944= (on ENST00000321322; = p.V884= on NM_020693.4) | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100356446; called by muse, mutect2, varscan2
- DSE | c.408G>A p.Q136= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV100528668; called by muse, mutect2, varscan2
- EEPD1 | c.1656C>T p.N552= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs553844659, COSV54198170; called by muse, mutect2, varscan2
- EGR1 | c.102G>A p.K34= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs368477832, COSV53518271; called by muse, mutect2, varscan2
- EPB41L1 | c.633G>A p.T211= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as rs752354193, COSV52437590; called by muse, mutect2, varscan2
- EPN1 | c.1581G>A p.T527= (on ENST00000270460 / NM_001321263.1; = p.T501= on NM_013333.3) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs201001431; called by muse, mutect2, varscan2
- FAM3D | c.129G>A p.S43= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs150004904; called by muse, mutect2, varscan2
- FAM47C | c.2784T>C p.S928= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV100792774; called by muse, mutect2, varscan2
- FANCF | c.846T>C p.G282= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100541848; called by muse, mutect2
- FOXP1 | c.87C>T p.C29= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as rs550457312, COSV59516564; called by muse, mutect2, varscan2
- FREM2 | c.6615C>T p.D2205= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs773245067, COSV54831542; called by muse, mutect2, varscan2
- FRS3 | c.768C>T p.C256= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52484206; called by muse, mutect2, varscan2
- GABBR2 | c.885G>A p.T295= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs200940989; called by muse, mutect2, varscan2
- GATAD2A | c.558C>T p.T186= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs142000821; called by muse, mutect2, varscan2
- GCNT3 | c.330T>C p.C110= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV101251843; called by muse, mutect2, varscan2
- GK5 | c.159T>G p.L53= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV101242261; called by muse, mutect2
- GPR35 | c.594G>A p.L198= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV100166586; called by muse, mutect2, varscan2
- GRIA2 | c.108C>T p.G36= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV52385756; called by muse, mutect2, varscan2
- GRM2 | c.1173G>A p.A391= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs971601071, COSV99622986; called by muse, mutect2
- GUK1 | c.303C>T p.D101= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs763681818, COSV100451738; called by muse, mutect2, varscan2
- GZF1 | c.144C>T p.A48= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100582596; called by muse, mutect2, varscan2
- H2BC17 | c.261C>G p.R87= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100377521; called by muse, mutect2
- HAPLN4 | c.360C>T p.G120= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1198743921, COSV99363905; called by muse, mutect2, varscan2
- HAUS4 | c.1053G>A p.K351= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV99246991; called by muse, mutect2
- HAUS4 | c.816C>T p.C272= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs376281728, COSV52827307; called by muse, mutect2, varscan2
- HEATR4 | c.459A>T p.P153= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100620470; called by muse, mutect2, varscan2
- HTR5A | c.636G>A p.P212= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1162409501, COSV55287343, COSV99839482; called by muse, mutect2, varscan2
- IDO2 | c.966G>A p.L322= (on ENST00000389060; = p.L335= on NM_194294.2) | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100584823; called by muse, mutect2, varscan2
- IFNLR1 | c.1356C>T p.G452= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV100552221; called by muse, mutect2, varscan2
- IFT57 | c.39G>A p.L13= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99197780; called by muse, mutect2, varscan2
- IL1RAPL1 | c.679A>C p.R227= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV56241048, COSV56251680; called by muse, mutect2, varscan2
- ILDR2 | c.174C>T p.F58= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV99614066; called by muse, mutect2, varscan2
- INPP5J | c.1626C>T p.G542= (on ENST00000331075 / NM_001284285.2; = p.G174= on NM_001002837.2) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs560088748, COSV100459591; called by muse, mutect2, varscan2
- ITGB4 | c.1776A>G p.G592= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV99564316; called by mutect2, varscan2
- JAZF1 | c.432C>T p.S144= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs146807750; called by muse, mutect2, varscan2
- KCND3 | c.384C>T p.I128= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1423401349, COSV100137806; called by muse, mutect2, varscan2
- KCNS2 | c.627G>A p.L209= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99751286; called by muse, mutect2
- KIAA1210 | c.2343A>G p.S781= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV101274290; called by muse, mutect2, varscan2
- KIF6 | c.2133G>A p.Q711= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99759564; called by muse, mutect2, varscan2
- KIFAP3 | c.274C>T p.L92= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV100847007; called by muse, mutect2, varscan2
- KLHDC8A | c.258C>T p.G86= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as rs922992949, COSV65678712; called by muse, mutect2
- KLRC1 | c.351C>T p.G117= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV61725102; called by muse, mutect2, varscan2
- KRTAP10-4 | c.69C>T p.C23= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs782379634, COSV100554457; called by muse, mutect2, varscan2
- KRTAP20-1 | c.162T>C p.G54= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100228801; called by muse, mutect2, varscan2
- LIG3 | c.1311C>A p.A437= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV99252863; called by muse, mutect2, varscan2
- LIN54 | c.1638C>T p.C546= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100464778; called by muse, mutect2, varscan2
- LPIN1 | c.1065G>A p.A355= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs969954737, COSV99877810; called by muse, mutect2, varscan2
- LRRK2 | c.4623G>A p.V1541= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1330572464, COSV100110700; called by muse, mutect2, varscan2
- LTA4H | c.255G>A p.S85= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs111742986, COSV99957164; called by muse, mutect2, varscan2
- MAGEA11 | c.849C>T p.D283= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV100290586; called by muse, mutect2, varscan2
- MED12L | c.2538A>G p.L846= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV56383165, COSV99853791; called by muse, mutect2
- MIS18A | c.465G>A p.T155= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1240442881, COSV99267083; called by muse, mutect2, varscan2
- MMEL1 | c.1200C>G p.V400= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99984082; called by muse, mutect2, varscan2
- MUC16 | c.23460G>A p.R7820= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV67445089; called by muse, mutect2, varscan2
- MUC17 | c.7149C>T p.D2383= | Silent (SNP) | VAF 26/318 reads (8%) | catalogued as rs138267850, COSV100075844, COSV60305969; called by muse, mutect2
- NBEAL2 | c.2664C>T p.C888= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs780626024, COSV99436613; called by muse, mutect2, varscan2
- NCAM2 | c.2274T>G p.A758= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs267606086, COSV53108393, COSV99523857; called by muse, mutect2, varscan2
- NEK6 | c.630G>A p.T210= | Silent (SNP) | VAF 27/262 reads (10%) | catalogued as rs1004721809, COSV57220356; called by muse, mutect2, varscan2
- NELL2 | c.1083C>T p.C361= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2
- NFAT5 | c.234C>T p.G78= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs750127974, COSV100590944; called by muse, mutect2, varscan2
- NINL | c.2397C>T p.C799= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1195547537, COSV99625696; called by muse, mutect2, varscan2
- NLRX1 | c.777T>C p.C259= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV99424498; called by muse, mutect2, varscan2
- NOTCH4 | c.4515C>T p.G1505= | Silent (SNP) | VAF 16/372 reads (4%) | catalogued as rs752383712, COSV100900791; called by muse, mutect2
- NRG3 | c.243C>T p.L81= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs1010732697, COSV100932182; called by muse, mutect2, varscan2
- NUP133 | c.3273T>C p.D1091= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV99773151; called by muse, mutect2, varscan2
- OPLAH | c.936C>A p.G312= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV101470790; called by muse, mutect2, varscan2
- OXA1L | c.1392C>T p.N464= (on ENST00000285848; = p.N404= on NM_005015.5) | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as rs764833639, COSV99591206; called by muse, mutect2
- PARP2 | c.843T>G p.S281= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV99162995; called by muse, mutect2, varscan2
- PAX4 | c.270G>A p.Q90= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV100490208; called by muse, mutect2, varscan2
- PCDH12 | c.1167C>T p.V389= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs1179487364, COSV99190852; called by muse, mutect2
- PCDHB9 | c.1965C>A p.T655= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1677G>A p.A559= | Silent (SNP) | VAF 13/140 reads (9%) | catalogued as COSV65296420; called by muse, mutect2
77 further variants in this file (0 protein-altering or splice-affecting, 59 silent, 18 other) are not listed here.
